Somatic mutation profile of tumor specimen TCGA-QR-A6H3-01A (aliquot TCGA-QR-A6H3-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H3, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 41.4 years (15,106 days).
Specimen TCGA-QR-A6H3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27946554-d7b8-41e6-9b8a-2f3f1a772232.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H3-10A (Blood Derived Normal), aliquot TCGA-QR-A6H3-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f974c6e6-191b-460c-81bb-b6bd5cf413f8

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLG5 | c.3335G>T p.R1112L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs372580241, COSV64948147; called by muse, mutect2, varscan2
- ELF3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs779747541, COSV62838350, COSV62839393; called by muse, mutect2, varscan2
- LILRB5 | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EIF2AK1 | c.621T>G p.V207= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- KRTAP1-1 | c.369C>T p.C123= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
